Surgical pathology report (de-identified scan), TCGA case TCGA-XU-AAY0, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-AAY0-01A (Primary Tumor).

[page 1 of 3]
ICD O-3
Thymoma, type AB
malignant 852/3
Site: Thymus 1379
p 5/2/14

Patient Name:

MRN:

DOB: (Age:)

Gender: F

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Thymus: anterior mediastinal tumor and total thymus-stitch marks open biopsy site

DIAGNOSIS

1. Mediastinum, resection (anterior mediastinal tumor and total thymus):

a) Thymoma, WHO type AB, with: (see Comment)

i) Greatest tumor dimension = 8.6 cm

ii) Focal microscopic transcapsular invasion present

iii) Resection margins negative for tumor

b) Organizing hematoma with surrounding foreign body giant cell reaction and fibrosis, consistent with biopsy site

c) Thymic tissue with involutional changes

SYNOPTIC DATA

Specimen:	Thymus
Procedure:	Thymectomy
Specimen Integrity:	Intact
Specimen Weight:	234(g)
Tumor Size:	Greatest dimension: 8.6 cm
	Additional Dimension: 8.5 cm
	Additional Dimension: 4.7 cm
Histologic Type:	Type AB thymoma
Tumor Extension:	Other: microscopic transcapsular
invasion	
Margins:	Margins uninvolved by tumor
	Distance of tumor from closest
margin: 6 mm	
Treatment Effect:	Not applicable
Lymph-Vascular Invasion:	Not identified
Regional Lymph Nodes:	Cannot be assessed
	Number examined: 0

Status: complete

Page: 1 of 3

[page 2 of 3]
Patient Name:

MRN:

DOB: (Age:)

Gender:F

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

Number involved: 0

Pathologic Staging (Modified Masaoka):

Stage IIa: Microscopic transcapsular

invasion

Implants/Distant Metastasis:

Cannot be assessed

Additional Pathologic Findings:

Age-appropriate involution changes

Other: resolving hematoma and

foreign body giant cell reaction at previous biopsy site

COMMENT

Sections show an encapsulated tumor composed predominantly of nodular proliferations of small lymphocytes admixed with lesser numbers of bland epithelioid cells (90-95% of the tumor), separated by fibrous septae. These are admixed with scattered areas composed of bland spindle cells containing few lymphocytes (5-10% of the tumor). The tumor appears to be completely encapsulated, but a single focus of microscopic transcapsular invasion is identified (block 1H). However, the tumor appears to be covered with ample adipose tissue at this point (approx. 0.8 cm from the tumor to the painted surface). An area overlying the tumor marked with a stitch shows a resolving hematoma with surrounding foreign body giant cell response and dense fibrosis, consistent with the previous open biopsy site. The tumor appears encapsulated in this area, with tumor cells 0.6 cm from the cauterized margin of this site. Immunohistochemical staining confirming thymic derivation were previously performed and were not repeated here. The overall findings remain of a WHO type AB thymoma, with focal microscopic transcapsular invasion (modified Masaoka stage IIa).

ELECTRONICALLY VERIFIED BY:

GROSS DESCRIPTION

1. The specimen container labeled with the patient's name and as "anterior mediastinal tumor and total thymus-stitch marks open biopsy site " contains an oval-shaped encapsulated mass with attached fibroadipose tissue, grossly consistent with thymus received in 10% buffered formalin. It measures 13.5 x 10 x 5.2 cm in overall dimension

Status: complete

Page: 2 of 3

[page 3 of 3]
Patient Name:

MRN:

DOB: (Age:)

Gender: F

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

and weighs 234 g. There is a stitch attached to a portion of adherent fibrous tissue indicating the open biopsy site. This portion of fibrous tissue measures 2.7 x 1.8 x 0.7 cm. The entire surface of the specimen is painted with Silver nitrate and the adherent fibrous tissue over-coated with India ink. The mass measures 8.6 x 8.5 x 4.7 cm and is firm, multilobular, homogeneous tan with whitish fibrotic areas admixed. The capsule is overall smooth except for the stitch area. Sections of the mass and thymic tissue stored frozen. Representative sections submitted as follows:

1A-1H sections from the open biopsy surface (1A-1D-includes the open biopsy site).

1I-1M sections from the opposite (deep) surface, with overlying fatty tissue.

1N, 1O sections from mid tumor.

1P, 1Q sections from fibrofatty tissue consistent with thymic tissue.

Status: complete

Page: 3 of 3

Source: NCI Genomic Data Commons file 00c0d5ed-3c5e-43be-b405-db3f7ab8deb7 (TCGA-XU-AAY0.FE9A7EDE-B8DF-411D-87EE-B2C9DD2793BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).